Somatic mutation profile of tumor specimen TCGA-66-2788-01A (aliquot TCGA-66-2788-01A-01D-0983-08) from TCGA case TCGA-66-2788, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 56.5 years (20,637 days).
Specimen TCGA-66-2788-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9b3e71d-afa7-485f-8a8f-133c54407951.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-66-2788-11A (Solid Tissue Normal), aliquot TCGA-66-2788-11A-01D-0983-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8aad44ed-2d38-4879-bb55-eac1408d3f5d

The open-access MAF lists 222 somatic variants for this specimen: 171 protein-altering or splice-affecting, 44 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 146, Silent 44, Nonsense Mutation 13, Frame Shift Del 8, Splice Site 3, RNA 2, 3'UTR 2, 5'UTR 1, Intron 1, Splice Region 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CAPN3 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274808359, CM994189, COSV58820033; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.375+1G>T p.X125_splice | Splice Site (SNP) | VAF 15/66 reads (23%) | hotspot (GDC flag); catalogued as CS951538, COSV52663569, COSV52668477, COSV52702628; called by muse, mutect2, varscan2
- ABCC5 | c.1810C>G p.L604V | Missense Mutation (SNP) | VAF 34/379 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); catalogued as COSV55594718; called by muse, mutect2
- ADGRA3 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.031); catalogued as COSV51566864; called by muse, mutect2, varscan2
- ADGRE3 | c.1841G>C p.R614T | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV53733618; called by muse, mutect2, varscan2
- AFDN | c.1855A>G p.I619V | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.72); PolyPhen benign (0.12); catalogued as COSV60052862; called by muse, mutect2, varscan2
- AMY2B | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 41/296 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.368); catalogued as rs780514402, COSV63716568; called by muse, mutect2, varscan2
- ANKRD30A | c.1307C>T p.S436F (on ENST00000611781; = p.S380F on NM_052997.2) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.272); catalogued as COSV64617464; called by muse, mutect2, varscan2
- APAF1 | c.1455C>G p.N485K (on ENST00000551964 / NM_181861.2; = p.N474K on NM_001160.3) | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.216); catalogued as COSV59666848; called by muse, mutect2, varscan2
- ARHGAP11A | c.1483G>T p.G495C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV64381489; called by muse, mutect2, varscan2
- ARHGAP15 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV54514131; called by muse, mutect2, varscan2
- ATP10A | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63521664; called by muse, mutect2, varscan2
- ATRIP | c.2348T>C p.V783A (on ENST00000320211 / NM_130384.3; = p.V756A on NM_032166.4) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV56497815; called by muse, mutect2, varscan2
- AURKC | c.592A>G p.T198A (on ENST00000302804 / NM_001015878.2; = p.T164A on NM_003160.3) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV57139653; called by muse, mutect2, varscan2
- AZIN1 | c.476A>G p.D159G | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.415); catalogued as COSV61480978; called by muse, mutect2, varscan2
- BPIFB3 | c.1301C>A p.A434E | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as COSV64957923; called by muse, mutect2, varscan2
- BTBD7 | c.1403T>C p.I468T | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as COSV58289378; called by muse, mutect2
- BTBD7 | c.110A>G p.Y37C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs200455654; called by muse, mutect2, varscan2
- C10orf71 | c.1490C>A p.P497H | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV60511060; called by muse, mutect2, varscan2
- C12orf43 | c.577T>G p.L193V | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.152); catalogued as COSV56568151; called by muse, mutect2, varscan2
- CACNB4 | c.464T>C p.L155P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV52400216; called by muse, mutect2, varscan2
- CADPS2 | c.2656G>T p.D886Y | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs766972414, COSV57379184; called by muse, mutect2, varscan2
- CAPN1 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV54200801; called by muse, mutect2, varscan2
- CASP1 | c.907G>T p.G303* (on ENST00000436863 / NM_033292.4; = p.G282* on NM_001223.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 9/34 reads (26%) | catalogued as COSV62057290; called by muse, mutect2, varscan2
- CD163L1 | c.3205G>A p.D1069N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs749297464, COSV58022415; called by muse, mutect2, varscan2
- CD1B | c.448G>A p.V150M | Missense Mutation (SNP) | VAF 48/227 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.04); catalogued as COSV63804948; called by muse, mutect2, varscan2
- CD1C | c.720G>T p.M240I | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as COSV63807239; called by muse, mutect2, varscan2
- CD8A | c.331G>T p.G111C | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM012083, COSV52158940; called by muse, mutect2, varscan2
- CDC42BPB | c.4690G>C p.E1564Q | Missense Mutation (SNP) | VAF 78/224 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.205); catalogued as COSV63476366; called by muse, mutect2, varscan2
- CEACAM5 | c.406G>A p.G136S | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.766); catalogued as COSV55754014; called by muse, mutect2, varscan2
- CENPQ | c.756G>T p.K252N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV59921934; called by mutect2, varscan2
- CEP152 | c.4438G>A p.D1480N (on ENST00000380950 / NM_001194998.2; = p.D1424N on NM_014985.4) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.599); catalogued as COSV57859113, COSV57862945; called by muse, mutect2, varscan2
- CEP162 | c.743C>G p.S248C | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs772030676, COSV57622879; called by muse, mutect2, varscan2
- CEP350 | c.5642G>C p.R1881P | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100854275, COSV62607890, COSV62608093; called by muse, mutect2, varscan2
- CEP85L | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV63826780; called by muse, mutect2, varscan2
- CHD7 | c.308C>T p.S103L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1242372187, COSV71113492; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRM2 | c.937G>T p.G313C | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.549); catalogued as COSV57780750; called by muse, varscan2
- CIAO3 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as COSV52400498; called by muse, mutect2, varscan2
- CMTR1 | c.682C>G p.R228G | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV65091429; called by muse, mutect2, varscan2
- COL19A1 | c.3212C>G p.P1071R | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as COSV59583018; called by muse, mutect2, varscan2
- COL4A2 | c.1039G>T p.G347* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV64632304; called by muse, varscan2
- COL4A2 | c.1040G>C p.G347A | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV64632312; called by muse, varscan2
- CRADD | c.26T>A p.L9H | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60555630; called by muse, mutect2, varscan2
- CRB1 | c.977A>C p.H326P | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.821); catalogued as COSV66346212; called by muse, mutect2, varscan2
- CSRNP1 | c.1426G>A p.G476S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.017); catalogued as COSV56189475; called by muse, mutect2, varscan2
- CSRP3 | c.382T>A p.Y128N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV56390242; called by muse, mutect2, varscan2
- CUX1 | c.2978A>T p.Q993L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV52910575; called by muse, mutect2, varscan2
- DAG1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58182598; called by muse, mutect2, varscan2
- DCC | c.3291C>A p.N1097K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.325); catalogued as COSV71438744; called by muse, mutect2, varscan2
- DNAH11 | c.6403G>C p.E2135Q | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1203479848, COSV60959179; called by muse, mutect2, varscan2
- DOCK2 | c.4021G>C p.D1341H | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56979201; called by muse, mutect2, varscan2
- DSG1 | c.2812A>T p.S938C | Missense Mutation (SNP) | VAF 119/312 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.635); catalogued as COSV57138042, COSV57138388; called by muse, mutect2, varscan2
- EGFL6 | c.1316T>A p.L439* | Nonsense Mutation (SNP) | VAF 32/60 reads (53%) | catalogued as COSV63634746; called by muse, mutect2, varscan2
- EPS8L1 | c.1391G>A p.R464Q (on ENST00000201647 / NM_133180.3; = p.R337Q on NM_017729.3) | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1422867495, COSV52385039; called by muse, mutect2, varscan2
- FAM124B | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV54739599; called by muse, mutect2, varscan2
- FBXW11 | c.906G>T p.V302= | Splice Region (SNP) | VAF 15/51 reads (29%) | catalogued as COSV51612597; called by muse, mutect2, varscan2
- FCRL5 | c.654G>C p.E218D | Missense Mutation (SNP) | VAF 29/148 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.304); catalogued as COSV62518634; called by muse, mutect2, varscan2
- FCRL5 | c.353C>A p.S118Y | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.575); catalogued as COSV62518657; called by muse, mutect2, varscan2
- FRMPD2 | c.1179C>G p.F393L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as rs564503106, COSV59715898, COSV59722100; called by muse, mutect2, varscan2
- FUNDC1 | c.442G>A p.G148S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65181785; called by muse, mutect2, varscan2
- GABRG1 | c.496C>A p.R166S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs751946075, COSV54959520, COSV99778811; called by muse, varscan2
- GREB1 | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52193460; called by muse, mutect2, varscan2
- GRIN2A | c.3722G>A p.R1241Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.532); catalogued as rs886042648, COSV58022353; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRSF1 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV54656750; called by muse, mutect2
- GTF3C1 | c.5541del p.E1848Rfs*33 | Frame Shift Del (DEL) | VAF 6/37 reads (16%) | catalogued as rs763161381; called by mutect2, pindel
- H2AC12 | c.101T>G p.L34R | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.749); catalogued as COSV63616822, COSV63617521; called by muse, mutect2, varscan2
- HACE1 | c.576G>T p.R192S | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as COSV53506141; called by muse, mutect2, varscan2
- HMG20A | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60313821; called by muse, mutect2, varscan2
- HSF5 | c.1518A>C p.E506D | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as COSV100090493, COSV60418632; called by muse, mutect2, varscan2
- IKZF2 | c.575-2A>T p.X192_splice | Splice Site (SNP) | VAF 11/63 reads (17%) | catalogued as COSV59582480; called by muse, mutect2, varscan2
- INSRR | c.2486A>G p.K829R | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV63872721, COSV63876266; called by muse, mutect2, varscan2
- IPO5 | c.3145G>C p.E1049Q | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); catalogued as rs748198568, COSV104375406, COSV55158263; called by muse, mutect2, varscan2
- JCAD | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs927198945, COSV64758141; called by muse, mutect2, varscan2
- KCNK10 | c.1387A>G p.K463E | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); catalogued as COSV56650175; called by muse, mutect2, varscan2
- KIZ | c.1303A>T p.S435C | Missense Mutation (SNP) | VAF 38/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV55687303; called by muse, mutect2, varscan2
- KLKB1 | c.1694G>A p.G565D | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs150832692; called by muse, mutect2, varscan2
- KLRG1 | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV56944650; called by muse, mutect2, varscan2
- LCE1B | c.304G>T p.G102C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as rs1280471339, COSV63980557; called by muse, mutect2, varscan2
- LHX8 | c.655G>C p.V219L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV53959098; called by muse, mutect2, varscan2
- LRP4 | c.4691A>G p.Q1564R | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as COSV66137854; called by muse, mutect2, varscan2
- MAD1L1 | c.71G>T p.R24L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs758427190, COSV54248880; called by muse, mutect2, varscan2
- MAGEA11 | c.357C>A p.H119Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.932); catalogued as COSV60757728; called by muse, mutect2, varscan2
- MDGA2 | c.1603C>T p.Q535* (on ENST00000399232 / NM_001113498.2; = p.Q237* on NM_182830.4) | Nonsense Mutation (SNP) | VAF 16/85 reads (19%) | catalogued as rs776016249, COSV62108949; called by muse, mutect2, varscan2
- MKRN3 | c.295A>T p.I99F | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV58811524; called by muse, mutect2, varscan2
- MNDA | c.580A>C p.T194P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV63741744; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1574C>T p.S525L | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV64057146; called by muse, mutect2, varscan2
- MS4A14 | c.956A>G p.D319G | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV55737134; called by muse, mutect2, varscan2
- MS4A3 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV53937438; called by muse, mutect2, varscan2
- MTERF4 | c.301G>C p.D101H | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV54090497; called by muse, mutect2, varscan2
- MTOR | c.1207C>T p.R403* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV63876258; called by muse, mutect2, varscan2
- MUC16 | c.42886A>T p.T14296S | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.879); catalogued as COSV66695498; called by muse, mutect2, varscan2
- MUC17 | c.11618G>A p.S3873N | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.795); catalogued as COSV60299127; called by muse, mutect2, varscan2
- NCKAP5L | c.3783G>C p.R1261S | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as COSV60132321; called by muse, mutect2
- NFASC | c.2464G>T p.E822* (on ENST00000339876 / NM_001378329.1; = p.E818* on NM_015090.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV58375426; called by muse, mutect2, varscan2
- NFATC2IP | c.751G>T p.V251F | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV57911006; called by muse, mutect2, varscan2
- NKX6-1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55685516; called by muse, mutect2, varscan2
- OBI1 | c.85G>T p.V29F | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371472431, COSV56146730; called by muse, mutect2, varscan2
- OR13F1 | c.494C>A p.P165Q | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58252365; called by muse, mutect2, varscan2
- OR2L2 | c.237G>C p.K79N | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV63558584; called by muse, mutect2, varscan2
- OR2W1 | c.259G>T p.G87* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV65851817, COSV65852029; called by muse, mutect2, varscan2
- OR51S1 | c.507C>G p.F169L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as COSV59059042, COSV59059603; called by muse, mutect2, varscan2
- OR6B2 | c.892A>T p.K298* | Nonsense Mutation (SNP) | VAF 18/126 reads (14%) | catalogued as COSV53155973; called by muse, mutect2, varscan2
- OR8B2 | c.728C>G p.S243C | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764574015, COSV100899467; called by muse, mutect2, varscan2
- OR8U1 | c.88C>A p.L30I | Missense Mutation (SNP) | VAF 37/152 reads (24%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as COSV100164069; called by muse, varscan2
- PAN2 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 35/132 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57754103; called by muse, mutect2, varscan2
- PARD3B | c.3556G>C p.D1186H (on ENST00000406610 / NM_001302769.2; = p.D1117H on NM_057177.7) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV62524630; called by muse, mutect2, varscan2
- PASK | c.3124G>T p.E1042* | Nonsense Mutation (SNP) | VAF 11/79 reads (14%) | catalogued as COSV52158183; called by muse, mutect2, varscan2
- PCDH17 | c.3100T>A p.S1034T | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.867); catalogued as COSV64977556; called by muse, mutect2, varscan2
- PCK1 | c.997T>C p.F333L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs749448028, COSV60130305; called by muse, varscan2
- PCNX2 | c.5662G>C p.G1888R | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as COSV50803020, COSV50853372; called by muse, mutect2, varscan2
- PDE10A | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as COSV63103325; called by muse, mutect2, varscan2
- PDYN | c.487C>T p.L163F | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1333307212, COSV54103018; called by muse, mutect2, varscan2
- PFKM | c.1381G>C p.G461R | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV56659578; called by muse, mutect2, varscan2
- PGBD1 | c.877G>T p.A293S | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as COSV52555363; called by muse, mutect2, varscan2
- PHACTR1 | c.295G>A p.V99I | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as rs911332535, COSV60677392; called by muse, mutect2, varscan2
- PIK3R4 | c.1906C>G p.L636V | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV63243164; called by muse, mutect2, varscan2
- PRAMEF12 | c.1060G>T p.D354Y | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.846); catalogued as COSV63216253; called by muse, mutect2, varscan2
- PRKG2 | c.1239A>C p.E413D | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as COSV52327117, COSV52330064; called by muse, mutect2, varscan2
- PTEN | c.578del p.L193Rfs*6 | Frame Shift Del (DEL) | VAF 38/122 reads (31%) | catalogued as COSV64289342; called by mutect2, pindel*, varscan2
- PTGFR | c.979G>T p.V327F | Missense Mutation (SNP) | VAF 13/74 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as rs922128019, COSV66116104; called by muse, mutect2, varscan2
- PTPRO | c.904A>C p.S302R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.075); catalogued as COSV55519267; called by muse, mutect2, varscan2
- RAD51 | c.200G>T p.S67I | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1163399253, COSV51113232; called by muse, mutect2, varscan2
- RALGAPA2 | c.5026G>T p.D1676Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52507050; called by muse, mutect2, varscan2
- RGS6 | c.1033G>A p.V345M | Missense Mutation (SNP) | VAF 69/194 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.197); catalogued as COSV59592981; called by muse, mutect2, varscan2
- RYR2 | c.5628A>T p.Q1876H | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV63705267; called by muse, mutect2, varscan2
- SATL1 | c.350C>G p.S117* (on ENST00000395409; = p.S304* on NM_001012980.2) | Nonsense Mutation (SNP) | VAF 11/30 reads (37%) | catalogued as COSV60577984; called by muse, mutect2, varscan2
- SCN10A | c.68A>G p.E23G | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs1456404908, COSV71862419; called by muse, mutect2, varscan2
- SCN7A | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (1); PolyPhen probably damaging (0.989); catalogued as COSV69273812; called by muse, mutect2, varscan2
- SFI1 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV66292399; called by muse, varscan2
- SI | c.4703C>A p.P1568H | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52279885, COSV52294175; called by muse, mutect2, varscan2
- SIPA1L1 | c.2554G>T p.E852* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV62169238, COSV62171156; called by muse, mutect2, varscan2
- SLC5A8 | c.1539G>C p.M513I | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.065); catalogued as COSV73311040; called by muse, mutect2, varscan2
- SLIT2 | c.1644G>T p.L548F | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV56588468; called by muse, mutect2, varscan2
- SPTA1 | c.437T>C p.L146P | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.851); catalogued as COSV63757531; called by muse, mutect2, varscan2
- SRSF7 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV57446288; called by muse, mutect2, varscan2
- STXBP5L | c.1885A>G p.I629V | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV56528070; called by muse, mutect2, varscan2
- SYNE2 | c.1157A>T p.Y386F | Missense Mutation (SNP) | VAF 85/240 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.02); catalogued as COSV59963871; called by muse, mutect2, varscan2
- TDRD1 | c.2120G>T p.W707L | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV52594256; called by muse, mutect2, varscan2
- TENM4 | c.7315C>A p.L2439I | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.978); catalogued as COSV53657545; called by muse, mutect2, varscan2
- TEX9 | c.298C>A p.H100N | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV61879998; called by muse, mutect2, varscan2
- TMC2 | c.1076+1G>A p.X359_splice | Splice Site (SNP) | VAF 14/76 reads (18%) | catalogued as rs752106637, COSV62656497; called by muse, mutect2, varscan2
- TNIK | c.1400A>G p.H467R | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs774132453, COSV52691649; called by muse, mutect2, varscan2
- TNR | c.3118C>G p.L1040V | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.057); catalogued as COSV54905757; called by muse, mutect2, varscan2
- TNR | c.856G>T p.G286C | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54905767; called by muse, mutect2, varscan2
- TOR1B | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV52214342; called by muse, mutect2, varscan2
- TPO | c.2684G>A p.R895K | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.006); catalogued as COSV61108464; called by muse, mutect2, varscan2
- TRAV21 | c.281T>C p.L94S | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs568300620; called by muse, varscan2
- TRIP10 | c.1687G>C p.E563Q (on ENST00000313244 / NM_001288962.2; = p.E507Q on NM_004240.4) | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55588095; called by muse, mutect2, varscan2
- TSSK4 | c.707A>T p.H236L | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV55304621; called by muse, mutect2, varscan2
- UGT1A4 | c.745G>T p.V249F | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV59395646; called by muse, mutect2, varscan2
- UGT2B10 | c.289T>C p.S97P | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.011); catalogued as COSV55322661; called by muse, mutect2, varscan2
- USB1 | c.311C>T p.P104L | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT tolerated (0.38); PolyPhen benign (0.08); catalogued as rs1213803624, COSV54683881; called by muse, mutect2, varscan2
- WDPCP | c.1848G>T p.L616F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.437); catalogued as COSV55428661; called by muse, mutect2, varscan2
- WDR33 | c.538G>T p.D180Y | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59251547, COSV59254101; called by muse, mutect2, varscan2
- WWOX | c.654del p.W218* | Frame Shift Del (DEL) | VAF 67/305 reads (22%) | catalogued as COSV68342025; called by mutect2, pindel, varscan2
- XRCC6 | c.800T>C p.I267T | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as rs369020045, COSV63158546; called by muse, mutect2, varscan2
- ZBTB8A | c.541A>G p.N181D | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs1484150103, COSV57143778; called by muse, mutect2, varscan2
- ZNF233 | c.1283G>T p.W428L | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.045); catalogued as COSV100492410; called by muse, varscan2
- ZNF415 | c.860T>A p.L287H | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV54703912, COSV99701576; called by muse, mutect2, varscan2
- ZNF667 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as rs758989279, COSV52630841; called by muse, mutect2, varscan2
- ZNF804B | c.1430C>A p.P477Q | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60846215; called by muse, mutect2, varscan2
- ZNF827 | c.1996G>T p.E666* | Nonsense Mutation (SNP) | VAF 26/129 reads (20%) | catalogued as COSV65230511; called by muse, mutect2, varscan2
- ZPBP | c.716T>A p.L239Q | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV50428026, COSV50431125; called by muse, mutect2, varscan2
- GRIN3B | c.1245del p.K416Sfs*5 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | called by mutect2, varscan2
- KIR2DL4 | c.808C>G p.P270A (on ENST00000396284; = p.P231A on NM_001080770.2) | Missense Mutation (SNP) | VAF 62/306 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.858); called by muse, varscan2
- MSL3 | c.875_878del p.L292Qfs*23 (on ENST00000312196 / NM_078629.4; = p.L126Qfs*23 on NM_006800.4) | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | called by mutect2, pindel, varscan2
- NALCN | c.584del p.L195* | Frame Shift Del (DEL) | VAF 46/161 reads (29%) | called by mutect2, pindel, varscan2
- OR11H12 | c.794T>A p.L265Q | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by mutect2, varscan2
- TRAJ53 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 30/81 reads (37%) | PolyPhen benign (0.203); called by muse, mutect2, varscan2
- VGLL2 | c.280del p.D94Tfs*14 | Frame Shift Del (DEL) | VAF 8/59 reads (14%) | called by pindel, varscan2
- ZDHHC8 | c.2213del p.P738Qfs*31 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | called by mutect2, pindel
- AC092143.1 | c.1617G>T p.L539= | Silent (SNP) | VAF 57/184 reads (31%) | catalogued as COSV59248625; called by muse, mutect2, varscan2
- AK9 | c.3030G>A p.Q1010= | Silent (SNP) | VAF 15/117 reads (13%) | catalogued as rs924637334, COSV58137185; called by muse, mutect2, varscan2
- ANK1 | c.2691G>A p.E897= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as rs373534758; called by muse, mutect2, varscan2
- APBB2 | c.297G>T p.L99= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV55959615; called by muse, mutect2, varscan2
- ATIC | c.459G>C p.V153= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV52694826; called by mutect2, varscan2
- ATP1A2 | c.1092G>T p.T364= | Silent (SNP) | VAF 18/104 reads (17%) | catalogued as COSV63405337; called by muse, mutect2, varscan2
- BEND4 | c.729T>C p.S243= | Silent (SNP) | VAF 10/81 reads (12%) | catalogued as COSV72469318; called by muse, mutect2, varscan2
- C2orf78 | c.1686C>T p.I562= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV68518826; called by muse, mutect2, varscan2
- CD37 | c.75C>A p.L25= | Silent (SNP) | VAF 73/360 reads (20%) | catalogued as COSV60545034; called by muse, mutect2, varscan2
- CEP85L | c.585A>G p.Q195= | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV63826789; called by muse, mutect2, varscan2
- CSMD1 | c.2967G>A p.E989= (on ENST00000520002; = p.E988= on NM_033225.6) | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV59365023; called by mutect2, varscan2
- CYLC1 | c.1896A>T p.P632= | Silent (SNP) | VAF 12/19 reads (63%) | catalogued as COSV61414889; called by muse, mutect2, varscan2
- DHRSX | c.726G>T p.V242= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV58137655; called by muse, mutect2, varscan2
- DUOX1 | c.456C>T p.D152= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as COSV58484986; called by muse, mutect2
- DYNC2I1 | c.1677G>T p.P559= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs373874385, COSV68104224, COSV68106555; called by muse, mutect2, varscan2
- GRID2 | c.2640T>A p.R880= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV56246331; called by muse, mutect2, varscan2
- HEPH | c.2208T>C p.Y736= (on ENST00000343002; = p.Y469= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV57969622; called by muse, mutect2, varscan2
- LILRB5 | c.1236C>A p.P412= | Silent (SNP) | VAF 11/73 reads (15%) | catalogued as COSV100300688; called by muse, mutect2, varscan2
- LIMS1 | c.150C>T p.F50= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV57541518; called by muse, mutect2, varscan2
- LRRCC1 | c.2715G>C p.R905= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs777490527, COSV64485082; called by muse, mutect2, varscan2
- MS4A4A | c.123A>T p.G41= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV59702882; called by muse, mutect2, varscan2
- MUC3A | c.354C>G p.T118= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs752287360, COSV100114511, COSV100115157; called by muse, mutect2, varscan2
- MYO18B | c.6837C>T p.P2279= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs1439452542, COSV59144431; called by muse, mutect2, varscan2
- PCYOX1L | c.525C>G p.L175= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as rs746210485, COSV51004428; called by muse, mutect2, varscan2
- PDE4DIP | c.3267C>T p.T1089= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV57719994; called by muse, mutect2, varscan2
- PPIL2 | c.600A>T p.T200= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV58608474; called by muse, mutect2, varscan2
- RLN2 | c.375C>G p.L125= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV57731135; called by muse, mutect2, varscan2
- RYR2 | c.1146G>A p.V382= | Silent (SNP) | VAF 17/109 reads (16%) | catalogued as COSV63705263; called by muse, mutect2, varscan2
- RYR2 | c.7954C>T p.L2652= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV63705269; called by muse, mutect2
- SCP2D1 | c.225C>A p.T75= | Silent (SNP) | VAF 21/99 reads (21%) | catalogued as COSV53858432; called by muse, mutect2, varscan2
- SLC2A9 | c.357C>T p.I119= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs756012230, COSV53325954; called by muse, mutect2, varscan2
- SLC5A11 | c.1611C>A p.S537= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV61743105; called by muse, mutect2, varscan2
- SLC6A5 | c.2328C>A p.P776= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as COSV100117076, COSV54228824; called by muse, mutect2, varscan2
- SUOX | c.645C>T p.F215= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV56270598; called by muse, mutect2, varscan2
- TARDBP | c.345A>C p.T115= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as COSV53570915; called by muse, mutect2, varscan2
- TMEM131L | c.4173T>A p.P1391= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV53649046; called by muse, mutect2, varscan2
- TSBP1 | c.1056G>A p.G352= (on ENST00000617061; = p.G357= on NM_006781.5) | Silent (SNP) | VAF 40/133 reads (30%) | catalogued as rs1027247399, COSV66660497; called by muse, mutect2, varscan2
- TSKS | c.1353C>G p.R451= | Silent (SNP) | VAF 10/59 reads (17%) | catalogued as COSV55874161, COSV55878122; called by muse, varscan2
- TUBGCP2 | c.2385G>T p.R795= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV53307808; called by muse, mutect2, varscan2
- UNC5B | c.873G>A p.Q291= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs1243191923, COSV58980003; called by muse, mutect2, varscan2
- USP38 | c.771T>C p.T257= | Silent (SNP) | VAF 7/45 reads (16%) | catalogued as COSV61027050; called by muse, mutect2, varscan2
- ZEB1 | c.810C>T p.C270= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV58051607; called by muse, mutect2, varscan2
- ZNF622 | c.1329A>C p.R443= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as rs750998180, COSV58074957; called by muse, mutect2, varscan2
- ZZZ3 | c.2649C>T p.Y883= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as COSV66234823; called by muse, mutect2, varscan2
- AC073310.1 | n.356C>T | RNA (SNP) | VAF 51/162 reads (31%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73826082 A>T | 5'Flank (SNP) | VAF 30/79 reads (38%) | called by muse, mutect2, varscan2
- ANKRD35 | c.-2C>A | 5'UTR (SNP) | VAF 6/33 reads (18%) | catalogued as COSV100841823; called by muse, mutect2, varscan2
- ARSG | c.*1308C>A | 3'UTR (SNP) | VAF 17/82 reads (21%) | catalogued as COSV100048571; called by muse, mutect2, varscan2
- INSIG1 | c.*19T>G | 3'UTR (SNP) | VAF 15/63 reads (24%) | catalogued as COSV100453063; called by muse, mutect2, varscan2
- MIR646 | n.22G>T | RNA (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.10360+1646C>T | Intron (SNP) | VAF 22/111 reads (20%) | catalogued as rs1316384031, COSV60258552; called by muse, mutect2, varscan2
